Gene-level copy-number profile of tumor specimen C3N-00551-04 from CPTAC case C3N-00551, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 54.7 years (19,986 days).
Specimen C3N-00551-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e4b45ca-d288-4c17-80c3-8efe6e6c777e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00551-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/82db225e-27d3-44bc-b6cb-c3b909ba4545

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 8,270; copy number 2: 31,642; copy number 3: 15,639; copy number 4: 2,527; copy number 5: 118; copy number 6: 147; copy number 7: 47.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,098,660–12,159,148, 1 gene: AL589678.1.
- chr9:41,979,352–41,983,753, 1 gene (within-gene range 0–1): CR788268.1.
- chr9:42,183,659–42,354,454, 5 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 312 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:107,986,523–109,504,634, 29 genes, copy number 5: SLC5A7, LINC01593, ACTP1, LINC01594, SETD6P1, SULT1C3, WASF1P1, SULT1C2, SULT1C2P2, SULT1C2P1, GMCL1P2, SULT1C4, SMIM12P1, GCC2, GCC2-AS1, LIMS1, LIMS1-AS1, AC010095.1, RPL10P5, RANBP2, CCDC138, RPL39P16, EDAR, Metazoa_SRP, SH3RF3-AS1, SH3RF3, MIR4265, SNRPGP9, MIR4266.
- chr5:602,620–2,967,955, 60 genes, copy number 5–7: AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2.
- chr5:3,357,264–7,830,081, 61 genes, copy number 6–7 (broad region; genes not listed).
- chr5:10,352,701–13,944,543, 35 genes, copy number 5–6: AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1.
- chr9:61,190,003–61,212,373, 4 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4.
- chr11:68,154,863–68,615,334, 5 genes, copy number 5 (within-gene range 3–5): KMT5B, C11orf24, LRP5, PPP6R3, NDUFA3P2.
- chr14:18,333,726–18,419,273, 4 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:20,580,999–21,180,616, 19 genes, copy number 6: AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1, ERI2, RNU6-944P, REXO5, AC004381.2, DCUN1D3, LYRM1, DNAH3, AC008551.1, TMEM159.
- chr20:49,812,713–49,892,242, 1 gene, copy number 6 (within-gene range 4–6): SLC9A8.
- chr20:49,903,391–55,684,915, 89 genes, copy number 5–6 (broad region; genes not listed).
- chr22:15,282,557–15,350,043, 5 genes, copy number 5: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Autosomal genes at a single copy (total copy number 1): 5,929. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
